Somatic mutation profile of tumor specimen 76e77c6b-c80e-4391-bdbb-e1dcea (aliquot 76e77c6b-c80e-4391-bdbb-e1dcea_D6) from CPTAC case 04OV051, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV.
Specimen 76e77c6b-c80e-4391-bdbb-e1dcea: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b857881-edfb-4a88-8b64-dbcc3fa7a5c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen aecb5251-5486-4adb-b842-24a6dc (Blood Derived Normal), aliquot aecb5251-5486-4adb-b842-24a6dc_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf2975a2-c760-4ef3-8647-b873f57a0ae9

The open-access MAF lists 100 somatic variants for this specimen: 59 protein-altering or splice-affecting, 27 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 27, Intron 6, RNA 3, Nonsense Mutation 3, 3'UTR 2, Frame Shift Del 2, Splice Site 2, In Frame Ins 1, 5'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTX2 | c.235G>A p.E79K (on ENST00000408990 / NM_172337.3; = p.E87K on NM_021728.4) | Missense Mutation (SNP) | VAF 116/368 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs786205224, CM1411529, COSV59765795; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BEX3 | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.913); catalogued as COSV55421214; called by muse, mutect2, varscan2
- BRWD3 | c.4352G>T p.R1451L | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100956244, COSV64753818; called by muse, mutect2, varscan2
- DLGAP3 | c.1766C>A p.A589D | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1239732231; called by muse, mutect2, varscan2
- FCMR | c.450G>T p.M150I | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV65569740; called by muse, mutect2, varscan2
- GPR158 | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748267112, COSV66267465; called by muse, mutect2, varscan2
- HDAC6 | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 114/376 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs367939546; called by muse, mutect2, varscan2
- KCNG4 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100376951; called by muse, mutect2, varscan2
- KIAA1755 | c.3343G>T p.G1115W | Missense Mutation (SNP) | VAF 107/310 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV104379102; called by muse, mutect2, varscan2
- KNL1 | c.4660G>C p.V1554L (on ENST00000346991 / NM_170589.5; = p.V1528L on NM_144508.5) | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100706472; called by muse, mutect2, varscan2
- NLRP2 | c.2128T>C p.F710L | Missense Mutation (SNP) | VAF 131/440 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs776270073; called by muse, mutect2, varscan2
- SH3D21 | c.981G>C p.Q327H (on ENST00000453908 / NM_001162530.2; = p.Q216H on NM_024676.5) | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs777279979; called by muse, mutect2, varscan2
- TLK1 | c.1464G>C p.Q488H | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100688855; called by muse, mutect2, varscan2
- TRPM7 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.818); catalogued as rs565496924, COSV57922863; called by muse, mutect2, varscan2
- AANAT | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ACER3 | c.118A>T p.N40Y | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTRT1 | c.682A>G p.K228E | Missense Mutation (SNP) | VAF 180/628 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1888G>C p.A630P | Missense Mutation (SNP) | VAF 119/538 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADARB2 | c.2162G>A p.G721D | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ATP7A | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BACE1 | c.808A>C p.N270H | Missense Mutation (SNP) | VAF 93/138 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BEX3 | c.306C>A p.D102E | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- C5orf22 | c.1200G>C p.R400S | Missense Mutation (SNP) | VAF 58/81 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CARD11 | c.3250A>T p.K1084* | Nonsense Mutation (SNP) | VAF 66/147 reads (45%) | called by muse, mutect2, varscan2
- CATSPER1 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 42/396 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CCDC107 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 147/471 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COPA | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- DHX58 | c.998_1011del p.D333Afs*27 | Frame Shift Del (DEL) | VAF 55/109 reads (50%) | called by mutect2, pindel, varscan2
- DSCR8 | n.230-2A>T | Splice Site (SNP) | VAF 56/191 reads (29%) | called by mutect2, varscan2
- EPPK1 | c.6371C>T p.A2124V | Missense Mutation (SNP) | VAF 130/283 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- FER1L6 | c.3135C>A p.D1045E | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- GABRG3 | c.976T>C p.F326L | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GIPC3 | c.782A>C p.E261A | Missense Mutation (SNP) | VAF 162/310 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GPR173 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 46/379 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- HIP1 | c.2781G>T p.K927N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- HOXA2 | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HPS5 | c.1947A>T p.K649N (on ENST00000349215 / NM_181507.2; = p.K535N on NM_007216.4) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KIAA0319 | c.841_886del p.E281Pfs*37 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel
- LIPE | c.2048A>G p.Y683C | Missense Mutation (SNP) | VAF 134/194 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- MUC16 | c.37963A>C p.S12655R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2
- MUC17 | c.3488C>A p.A1163E | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEDD4 | c.929A>C p.E310A | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NTRK1 | c.891C>A p.H297Q | Missense Mutation (SNP) | VAF 104/297 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGDH | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OGDH | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4X2 | c.507T>G p.Y169* | Nonsense Mutation (SNP) | VAF 22/618 reads (4%) | called by muse, mutect2
- PLIN5 | c.1058A>G p.H353R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- PODN | c.1404G>T p.Q468H (on ENST00000395871; = p.Q420H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 142/457 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- POMK | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 77/345 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAD54L | c.1306_1307insCAG p.E435_E436insA | In Frame Ins (INS) | VAF 133/523 reads (25%) | called by pindel, varscan2
- SERTAD4 | c.507C>G p.D169E | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- SNRNP70 | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 92/156 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SNTG1 | c.1192-1_1202del p.X398_splice | Splice Site (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- SON | c.4564G>A p.D1522N | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- STAB2 | c.2791G>A p.V931M | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- SURF1 | c.832T>C p.W278R | Missense Mutation (SNP) | VAF 337/854 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TP53 | c.315_323del p.S106_G108del | In Frame Del (DEL) | VAF 50/106 reads (47%) | called by pindel, varscan2
- TRAV19 | c.330C>G p.Y110* | Nonsense Mutation (SNP) | VAF 134/387 reads (35%) | called by muse, mutect2, varscan2
- VPS28 | c.548+4G>T | Splice Region (SNP) | VAF 71/144 reads (49%) | called by muse, mutect2, varscan2
- ADGRA2 | c.1278G>T p.V426= | Silent (SNP) | VAF 71/223 reads (32%) | called by muse, mutect2, varscan2
- ATP5F1B | c.655T>C p.L219= | Silent (SNP) | VAF 28/46 reads (61%) | called by muse, mutect2, varscan2
- C20orf194 | c.3294G>A p.G1098= | Silent (SNP) | VAF 35/217 reads (16%) | called by muse, mutect2, varscan2
- DLGAP3 | c.1767C>A p.A589= | Silent (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2865T>G p.L955= | Silent (SNP) | VAF 92/259 reads (36%) | called by muse, mutect2, varscan2
- FAM86B1 | c.801G>A p.G267= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1475658645; called by mutect2, varscan2
- FCRL5 | c.2265C>T p.T755= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs766760827; called by muse, mutect2, varscan2
- GFRA1 | c.993C>T p.F331= | Silent (SNP) | VAF 20/323 reads (6%) | catalogued as COSV100815407; called by muse, mutect2
- GLB1 | c.834C>A p.G278= | Silent (SNP) | VAF 55/428 reads (13%) | called by muse, mutect2, varscan2
- GOLGB1 | c.9687C>T p.L3229= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as COSV58859487; called by muse, mutect2, varscan2
- IGSF1 | c.618C>A p.L206= | Silent (SNP) | VAF 70/199 reads (35%) | called by muse, mutect2, varscan2
- LRRN4CL | c.513C>T p.G171= | Silent (SNP) | VAF 75/275 reads (27%) | called by muse, mutect2, varscan2
- LYZL2 | c.15C>G p.P5= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- MEP1A | c.1728G>A p.L576= | Silent (SNP) | VAF 31/138 reads (22%) | called by muse, mutect2, varscan2
- MOB3C | c.432T>G p.P144= | Silent (SNP) | VAF 84/230 reads (37%) | called by muse, mutect2, varscan2
- MPEG1 | c.1323C>A p.L441= | Silent (SNP) | VAF 43/349 reads (12%) | called by muse, mutect2, varscan2
- NHSL2 | c.1407G>T p.S469= (on ENST00000510661; = p.S835= on NM_001013627.2) | Silent (SNP) | VAF 78/283 reads (28%) | catalogued as COSV65455013; called by muse, mutect2, varscan2
- OR5L1 | c.201C>T p.S67= | Silent (SNP) | VAF 123/447 reads (28%) | called by muse, mutect2, varscan2
- PJA1 | c.1086C>T p.D362= (on ENST00000361478 / NM_145119.4; = p.D174= on NM_022368.5) | Silent (SNP) | VAF 40/279 reads (14%) | catalogued as rs369648207; called by muse, mutect2, varscan2
- POTEG | c.1096C>T p.L366= | Silent (SNP) | VAF 12/143 reads (8%) | catalogued as rs773324509; called by muse, mutect2
- PSMB2 | c.510C>T p.R170= | Silent (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- SLC10A2 | c.60G>T p.V20= | Silent (SNP) | VAF 97/152 reads (64%) | called by muse, mutect2, varscan2
- SMARCA2 | c.2455C>A p.R819= | Silent (SNP) | VAF 41/170 reads (24%) | called by muse, mutect2, varscan2
- SNRNP40 | c.867G>C p.L289= | Silent (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- SOWAHD | c.561C>A p.G187= | Silent (SNP) | VAF 109/260 reads (42%) | called by muse, mutect2, varscan2
- STK36 | c.3693C>T p.C1231= | Silent (SNP) | VAF 118/353 reads (33%) | catalogued as rs762005504, COSV55331057; called by muse, mutect2, varscan2
- TRAF7 | c.1110G>A p.A370= | Silent (SNP) | VAF 37/286 reads (13%) | catalogued as rs779534022; called by muse, mutect2, varscan2
- AC007557.3 | n.2345A>C | RNA (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- AC008592.1 | chr5:95858916 G>C | 5'Flank (SNP) | VAF 70/210 reads (33%) | called by muse, mutect2, varscan2
- GCKR | c.969-27A>T | Intron (SNP) | VAF 23/581 reads (4%) | called by muse, mutect2
- GNAO1 | c.723+4027G>T | Intron (SNP) | VAF 59/194 reads (30%) | called by muse, mutect2, varscan2
- GOLGA8K | c.48+72G>A | Intron (SNP) | VAF 138/492 reads (28%) | called by muse, mutect2, varscan2
- GRIA1 | c.2385+748G>A | Intron (SNP) | VAF 59/123 reads (48%) | catalogued as rs774098513, COSV53622656; called by muse, mutect2, varscan2
- GTF2B | c.-30C>G | 5'UTR (SNP) | VAF 21/82 reads (26%) | catalogued as rs199559850; called by muse, mutect2, varscan2
- KCNA2 | c.*1146C>T | 3'UTR (SNP) | VAF 59/223 reads (26%) | catalogued as rs770970601; called by muse, mutect2, varscan2
- LINC01555 | n.325C>G | RNA (SNP) | VAF 65/202 reads (32%) | called by muse, mutect2, varscan2
- MON2 | chr12:62603000 C>G | 3'Flank (SNP) | VAF 35/96 reads (36%) | called by muse, mutect2, varscan2
- NCAN | c.3409+33_3409+61del | Intron (DEL) | VAF 37/160 reads (23%) | called by mutect2, pindel, varscan2
- NOP9 | c.*2705C>T | 3'UTR (SNP) | VAF 112/304 reads (37%) | catalogued as rs146748676; called by muse, mutect2, varscan2
- PPY2P | n.542C>G | RNA (SNP) | VAF 31/45 reads (69%) | called by muse, mutect2, varscan2
- SLC19A3 | c.150+1176T>G | Intron (SNP) | VAF 47/164 reads (29%) | called by muse, mutect2, varscan2
